Somatic mutation profile of tumor specimen TCGA-DX-A48O-01A (aliquot TCGA-DX-A48O-01A-11D-A307-09) from TCGA case TCGA-DX-A48O, project TCGA-SARC (Sarcoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Leiomyosarcoma, NOS; Tissue or organ of origin: Retroperitoneum; Age at diagnosis: 64.0 years (23,364 days).
Specimen TCGA-DX-A48O-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3c045d80-5532-4be6-bf06-2e242f885f76.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DX-A48O-10A (Blood Derived Normal), aliquot TCGA-DX-A48O-10A-01D-A307-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e8bd62d1-a588-467c-8d25-a83da05f6937

The open-access MAF lists 58 somatic variants for this specimen: 47 protein-altering or splice-affecting, 10 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 37, Silent 10, Nonsense Mutation 5, Frame Shift Del 2, Splice Site 1, RNA 1, Splice Region 1, Nonstop Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.473G>A p.R158H | Missense Mutation (SNP) | VAF 35/44 reads (80%) | hotspot (GDC flag); SIFT tolerated (0.1); PolyPhen possibly damaging (0.45); catalogued as rs587782144, CM102353, CM165595, CM994513, COSV52676395, COSV52678258, COSV52680378, COSV53545833; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- AEBP1 | c.2940C>A p.F980L | Missense Mutation (SNP) | VAF 49/99 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs776691425, COSV99788581; called by muse, mutect2, varscan2
- ANKEF1 | c.1180G>T p.E394* | Nonsense Mutation (SNP) | VAF 33/84 reads (39%) | catalogued as COSV101001000, COSV101001094; called by muse, mutect2, varscan2
- AP3B2 | c.3265T>G p.*1089Gext*16 (on ENST00000261722; = p.*1083Gext*16 on NM_004644.5) | Nonstop Mutation (SNP) | VAF 49/98 reads (50%) | catalogued as COSV99916212; called by muse, mutect2, varscan2
- BBS4 | c.711G>A p.K237= | Splice Region (SNP) | VAF 56/145 reads (39%) | catalogued as COSV99166402; called by muse, mutect2, varscan2
- CCNB3 | c.3349G>A p.D1117N | Missense Mutation (SNP) | VAF 11/132 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.427); catalogued as COSV99328744; called by muse, mutect2
- CD163 | c.1612G>T p.G538* | Nonsense Mutation (SNP) | VAF 69/134 reads (51%) | catalogued as COSV100775753; called by muse, mutect2, varscan2
- CELSR3 | c.9409C>T p.R3137C | Missense Mutation (SNP) | VAF 91/222 reads (41%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.04); catalogued as rs910673857, COSV51140153; called by muse, mutect2, varscan2
- CFAP47 | c.5065A>G p.M1689V | Missense Mutation (SNP) | VAF 101/206 reads (49%) | SIFT tolerated (0.19); PolyPhen benign (0.117); catalogued as COSV100545098; called by muse, mutect2, varscan2
- CYP2E1 | c.1150C>A p.P384T | Missense Mutation (SNP) | VAF 50/64 reads (78%) | SIFT deleterious (0); PolyPhen possibly damaging (0.886); catalogued as COSV53312478, COSV99428877; called by muse, mutect2, varscan2
- DENND4A | c.4010G>A p.W1337* | Nonsense Mutation (SNP) | VAF 134/314 reads (43%) | catalogued as COSV101475288; called by muse, mutect2, varscan2
- DLG3 | c.1506G>T p.R502S (on ENST00000374360 / NM_021120.4; = p.R165S on NM_020730.3) | Missense Mutation (SNP) | VAF 56/122 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.599); catalogued as COSV99529205, COSV99529320; called by muse, mutect2, varscan2
- FCGR2B | c.203C>T p.T68I | Missense Mutation (SNP) | VAF 57/545 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.985); catalogued as rs764194070, COSV99374960; called by muse, mutect2, varscan2
- FOXO4 | c.736A>G p.N246D | Missense Mutation (SNP) | VAF 11/100 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.027); catalogued as COSV100446826; called by muse, mutect2
- FRMPD3 | c.907C>G p.P303A | Missense Mutation (SNP) | VAF 25/60 reads (42%) | SIFT tolerated (0.54); PolyPhen possibly damaging (0.831); catalogued as rs1348843873, COSV99345945; called by muse, mutect2, varscan2
- FXN | c.299A>C p.Y100S (on ENST00000377270; = p.Y175S on NM_000144.5) | Missense Mutation (SNP) | VAF 72/177 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV101040057; called by muse, mutect2, varscan2
- FYB1 | c.2067A>C p.E689D (on ENST00000351578 / NM_199335.5; = p.E735D on NM_001465.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 31/78 reads (40%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.978); catalogued as COSV100685128; called by muse, mutect2, varscan2
- GEMIN5 | c.2828G>A p.G943E | Missense Mutation (SNP) | VAF 39/80 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99593768; called by muse, mutect2, varscan2
- IKZF3 | c.980C>T p.P327L | Missense Mutation (SNP) | VAF 39/85 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.772); catalogued as rs1181791231, COSV99499395; called by muse, mutect2, varscan2
- KCND1 | c.145C>T p.R49W | Missense Mutation (SNP) | VAF 5/84 reads (6%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.968); catalogued as rs1352604431, COSV54416262; called by muse, mutect2
- KCNMB4 | c.10C>T p.L4F | Missense Mutation (SNP) | VAF 7/71 reads (10%) | SIFT tolerated (0.14); PolyPhen benign (0.018); catalogued as rs760504525, COSV99253011; called by muse, mutect2
- MATR3 | c.356C>G p.A119G | Missense Mutation (SNP) | VAF 9/135 reads (7%) | SIFT deleterious (0.04); PolyPhen benign (0.091); catalogued as COSV100735139; called by muse, mutect2
- NEFM | c.1387G>T p.E463* | Nonsense Mutation (SNP) | VAF 30/62 reads (48%) | catalogued as COSV99647106; called by muse, mutect2, varscan2
- PCDHB13 | c.2279G>T p.G760V | Missense Mutation (SNP) | VAF 100/237 reads (42%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.291); catalogued as COSV99507019; called by muse, mutect2, varscan2
- PCNT | c.7687C>T p.Q2563* | Nonsense Mutation (SNP) | VAF 11/21 reads (52%) | catalogued as COSV100855240; called by muse, mutect2, varscan2
- PLS3 | c.325A>T p.T109S | Missense Mutation (SNP) | VAF 51/116 reads (44%) | SIFT tolerated (0.16); PolyPhen benign (0.058); catalogued as COSV99171624; called by muse, mutect2, varscan2
- PRKD3 | c.2221G>A p.A741T | Missense Mutation (SNP) | VAF 54/103 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV99305939; called by muse, mutect2, varscan2
- PRKDC | c.8126G>A p.G2709E | Missense Mutation (SNP) | VAF 22/258 reads (9%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as COSV100039317; called by muse, mutect2
- PTGS2 | c.117G>T p.Q39H | Missense Mutation (SNP) | VAF 37/132 reads (28%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as COSV100821713; called by muse, mutect2, varscan2
- RFPL3 | c.26C>A p.T9N | Missense Mutation (SNP) | VAF 100/246 reads (41%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.044); catalogued as COSV99967001; called by muse, mutect2, varscan2
- RIMS1 | c.4253C>G p.T1418R | Missense Mutation (SNP) | VAF 11/105 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs766306252, COSV53447587, COSV99325402; called by muse, mutect2, varscan2
- SPDYE2 | c.434T>G p.M145R | Missense Mutation (SNP) | VAF 6/482 reads (1%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs373691450; called by muse, mutect2
- STAB2 | c.1826G>C p.R609T | Missense Mutation (SNP) | VAF 56/129 reads (43%) | SIFT tolerated (0.58); PolyPhen benign (0.038); catalogued as COSV101185768; called by muse, mutect2, varscan2
- SYNCRIP | c.774G>C p.Q258H | Missense Mutation (SNP) | VAF 55/114 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.491); catalogued as COSV100784119; called by muse, mutect2, varscan2
- TFPI | c.406G>A p.G136S | Missense Mutation (SNP) | VAF 69/142 reads (49%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.951); catalogued as COSV51903981; called by muse, mutect2, varscan2
- TNF | c.85C>T p.R29W | Missense Mutation (SNP) | VAF 42/50 reads (84%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.938); catalogued as rs1260793650, COSV101403161, COSV69305377; called by muse, mutect2, varscan2
- TRIM21 | c.710A>G p.H237R | Missense Mutation (SNP) | VAF 41/52 reads (79%) | SIFT tolerated (0.61); PolyPhen benign (0); catalogued as rs1449309170, COSV99587598; called by muse, mutect2, varscan2
- TRPA1 | c.2063C>T p.A688V | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as COSV100083619, COSV100083762; called by muse, mutect2, varscan2
- TUBAL3 | c.457G>A p.G153S | Missense Mutation (SNP) | VAF 16/71 reads (23%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.987); catalogued as COSV100990493; called by muse, mutect2, varscan2
- UGT1A5 | c.210A>C p.K70N | Missense Mutation (SNP) | VAF 57/130 reads (44%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.948); catalogued as COSV100530032; called by muse, mutect2, varscan2
- USF3 | c.5578C>G p.P1860A | Missense Mutation (SNP) | VAF 43/110 reads (39%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.48); catalogued as rs373048207; called by muse, mutect2, varscan2
- WDFY3 | c.5923T>C p.C1975R | Missense Mutation (SNP) | VAF 19/250 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.333); catalogued as COSV99882754; called by muse, mutect2
- ZAN | c.4841T>C p.L1614P | Missense Mutation (SNP) | VAF 32/83 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.037); catalogued as COSV100769452; called by muse, mutect2, varscan2
- AVIL | c.2170C>A p.Q724K | Missense Mutation (SNP) | VAF 3/48 reads (6%) | SIFT tolerated (0.06); PolyPhen benign (0.146); called by muse, mutect2
- DUSP12 | c.908_927del p.Y303Wfs*2 | Frame Shift Del (DEL) | VAF 34/184 reads (18%) | called by mutect2, pindel, varscan2
- MEST | c.647+2del p.X216_splice | Splice Site (DEL) | VAF 40/108 reads (37%) | called by mutect2, pindel, varscan2
- PKHD1L1 | c.9863del p.N3288Ifs*2 | Frame Shift Del (DEL) | VAF 79/198 reads (40%) | called by mutect2, pindel, varscan2
- ATRNL1 | c.2436C>A p.G812= | Silent (SNP) | VAF 66/76 reads (87%) | catalogued as COSV100369949; called by muse, mutect2, varscan2
- GIMAP6 | c.264G>T p.G88= | Silent (SNP) | VAF 44/89 reads (49%) | catalogued as COSV100188154, COSV61033520; called by muse, mutect2, varscan2
- GPSM3 | c.282C>G p.A94= | Silent (SNP) | VAF 7/61 reads (11%) | catalogued as COSV100900539; called by muse, mutect2
- LILRB1 | c.1038C>A p.P346= (on ENST00000427581; = p.P310= on NM_006669.6) | Silent (SNP) | VAF 24/384 reads (6%) | catalogued as COSV100207097; called by muse, mutect2
- LRRIQ3 | c.492A>T p.I164= | Silent (SNP) | VAF 53/138 reads (38%) | catalogued as COSV100598585; called by muse, mutect2, varscan2
- LYAR | c.534G>T p.V178= | Silent (SNP) | VAF 6/86 reads (7%) | catalogued as COSV58642261; called by muse, mutect2
- PRKCD | c.837C>T p.L279= | Silent (SNP) | VAF 36/73 reads (49%) | catalogued as COSV100387760; called by muse, mutect2, varscan2
- RYR2 | c.9231G>A p.Q3077= | Silent (SNP) | VAF 69/195 reads (35%) | catalogued as COSV100769012; called by muse, mutect2, varscan2
- ZNF397 | c.291G>A p.Q97= | Silent (SNP) | VAF 22/46 reads (48%) | catalogued as COSV99734778; called by muse, mutect2, varscan2
- ZP4 | c.1063A>C p.R355= | Silent (SNP) | VAF 42/161 reads (26%) | catalogued as COSV100850632; called by muse, mutect2, varscan2
- FRMPD2B | n.741T>G | RNA (SNP) | VAF 83/373 reads (22%) | called by muse, mutect2, varscan2
